Gene-level copy-number profile of tumor specimen ALCH-B2E3-TTP1-A from ALCHEMIST case ALCH-B2E3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 56.1 years (20,499 days).
Specimen ALCH-B2E3-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0b823f02-e22f-4319-900b-a88ab401cd5e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2E3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/60a1b130-5443-4a95-b586-72d07b7a6ae0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 8,700; copy number 2: 49,854; copy number 3: 295; copy number 4: 3; copy number 5: 4; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:73,308,276–73,369,388, 1 gene (within-gene range 0–2): ARHGEF17.
- chr12:132,550,729–132,566,425, 2 genes (within-gene range 0–2): AC131212.3, AC131212.2.
- chr15:25,170,723–25,250,940, 44 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:76,993,359–77,037,475, 1 gene: PSTPIP1.
- chr22:41,229,510–41,240,931, 1 gene (within-gene range 0–2): CHADL.
- chr22:41,252,992–41,253,050, 1 gene (within-gene range 0–2): MIR6889.
- chr22:46,053,869–46,113,928, 1 gene (within-gene range 0–1): MIRLET7BHG.
- chr22:46,067,356–46,113,768, 5 genes (within-gene range 0–1): AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,615,581–18,757,906, 6 genes, copy number 5–15: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.

Autosomal genes at a single copy (total copy number 1): 5,856. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
